Somatic mutation profile of tumor specimen TCGA-ET-A25O-01A (aliquot TCGA-ET-A25O-01A-11D-A17V-08) from TCGA case TCGA-ET-A25O, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 35.4 years (12,924 days).
Specimen TCGA-ET-A25O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35a2bc0f-209d-4d26-be6e-66b0ebc7c451.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A25O-10A (Blood Derived Normal), aliquot TCGA-ET-A25O-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9466bbb-1f2d-4c0f-a4e3-8231464ee048

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- LRRC37A2 | c.3927A>C p.K1309N | Missense Mutation (SNP) | VAF 80/380 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.311); catalogued as COSV60236552; called by muse, mutect2, varscan2
- MAN2C1 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as rs1291957293, COSV51234754; called by muse, mutect2, varscan2
- OCLN | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV62285767; called by muse, mutect2, varscan2
- PKHD1 | c.3197C>T p.S1066L | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.342); catalogued as COSV61887908; called by muse, mutect2, varscan2
- SEC24D | c.73C>T p.H25Y | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.039); catalogued as COSV54882778; called by muse, mutect2, varscan2
- NOLC1 | c.1872A>T p.P624= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV64180829; called by muse, mutect2, varscan2
